Somatic mutation profile of tumor specimen TCGA-CG-4455-01A (aliquot TCGA-CG-4455-01A-01D-1158-08) from TCGA case TCGA-CG-4455, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 72.3 years (26,421 days).
Specimen TCGA-CG-4455-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55d1cc86-01b3-46d9-8dda-ba9cbc396f2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4455-10A (Blood Derived Normal), aliquot TCGA-CG-4455-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b06bb2b-7051-4508-bdca-3ff046380296

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 25, Silent 16, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL9 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.331); catalogued as rs369410953; called by muse, mutect2, varscan2
- AOC2 | c.1688A>T p.Q563L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99520349; called by muse, mutect2, varscan2
- BCOR | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV60717993; called by muse, mutect2, varscan2
- CCNA1 | c.1217A>C p.E406A | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV55223861; called by muse, mutect2, varscan2
- CFAP69 | c.2564T>A p.L855H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV60188309; called by muse, mutect2
- CUBN | c.8581C>T p.Q2861* | Nonsense Mutation (SNP) | VAF 23/156 reads (15%) | catalogued as COSV64726792; called by muse, mutect2, varscan2
- DDC | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63567667; called by muse, mutect2, varscan2
- DEFB131A | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV58416734; called by muse, mutect2
- DNAH11 | c.13112C>T p.P4371L | Missense Mutation (SNP) | VAF 41/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238638659, COSV60945958; called by muse, mutect2, varscan2
- DNAI2 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56762392; called by muse, mutect2, varscan2
- DPP10 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV59725034; called by muse, mutect2, varscan2
- FCHO1 | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV53185363; called by muse, mutect2, varscan2
- FNDC11 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64443508; called by muse, mutect2, varscan2
- ITGA8 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100959881, COSV65235595; called by muse, mutect2, varscan2
- MAP2K3 | c.152C>G p.T51S (on ENST00000342679 / NM_145109.3; = p.T22S on NM_002756.4) | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV57568673; called by muse, mutect2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs761471964; called by mutect2, varscan2
- PAK3 | c.467C>T p.T156I (on ENST00000262836 / NM_001324328.2; = p.T141I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV53280387; called by muse, mutect2, varscan2
- PCLO | c.9932A>C p.K3311T | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61614583, COSV61658327, COSV61664662; called by muse, mutect2, varscan2
- PLBD1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759241417, COSV53696255; called by muse, mutect2, varscan2
- POFUT1 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65338372; called by muse, mutect2, varscan2
- PTER | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV54347452; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 11/94 reads (12%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SERPINE1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 119/854 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs756762479, COSV56168966; called by muse, mutect2, varscan2
- SLC11A2 | c.877A>G p.I293V (on ENST00000394904 / NM_001379455.1; = p.I264V on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as rs1329917035, COSV50376345; called by muse, mutect2, varscan2
- SLC25A40 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62021647; called by muse, mutect2
- TRIM13 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.271); catalogued as rs376131356; called by muse, mutect2, varscan2
- UBR4 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64398922; called by muse, mutect2, varscan2
- VARS2 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58914609; called by muse, mutect2, varscan2
- ZBTB11 | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 52/520 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57246905; called by muse, mutect2
- GLYATL2 | c.113del p.N38Tfs*9 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.5215del p.H1739Tfs*5 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- ADGRG4 | c.9111G>T p.L3037= | Silent (SNP) | VAF 103/205 reads (50%) | catalogued as COSV54966344; called by muse, mutect2, varscan2
- AQR | c.1917C>T p.T639= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs575622885, COSV50052354; called by muse, mutect2, varscan2
- DUS1L | c.819C>T p.H273= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV57651295; called by muse, mutect2, varscan2
- FYN | c.354T>C p.D118= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV57620831; called by muse, mutect2
- MAP3K20 | c.801G>A p.T267= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs145549000, COSV59102513; called by muse, mutect2, varscan2
- MTSS1 | c.240C>T p.T80= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV61499964; called by muse, mutect2, varscan2
- MUC6 | c.6693T>C p.V2231= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV70149688; called by muse, mutect2, varscan2
- OR51B6 | c.477T>A p.V159= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV66513895; called by muse, mutect2, varscan2
- SOHLH1 | c.600G>A p.T200= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs374493888; called by muse, mutect2, varscan2
- SPATA31E1 | c.603C>T p.T201= | Silent (SNP) | VAF 22/185 reads (12%) | catalogued as COSV57795011; called by muse, mutect2, varscan2
- SYT4 | c.996C>T p.Y332= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV54903971; called by muse, mutect2
- TTLL4 | c.1752C>T p.P584= | Silent (SNP) | VAF 33/268 reads (12%) | catalogued as rs914304142, COSV51439310; called by muse, mutect2, varscan2
- UBR4 | c.10401G>A p.Q3467= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV64398914; called by muse, mutect2, varscan2
- UNC45B | c.1236G>A p.L412= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV52100470; called by muse, mutect2, varscan2
- UNC79 | c.7791G>A p.S2597= (on ENST00000393151 / NM_001346218.2; = p.S2420= on NM_020818.5) | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as rs200459525, COSV56384004; called by muse, mutect2, varscan2
- ZKSCAN5 | c.570A>G p.Q190= | Silent (SNP) | VAF 28/366 reads (8%) | catalogued as COSV58744502; called by muse, mutect2
